Gene-level copy-number profile of tumor specimen ALCH-B3JM-TTP1-A from ALCHEMIST case ALCH-B3JM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.0 years (28,140 days).
Specimen ALCH-B3JM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ce00fe26-1b0e-414c-9929-9c3473b227e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/78089e5f-5123-4a47-af3c-4c075876ca70

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 138; copy number 1: 5,354; copy number 2: 51,107; copy number 3: 2,232; copy number 4: 52; copy number 5: 2; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 2 genes: CASZ1, AL139423.1.
- chr1:109,249,539–109,275,751, 1 gene: CELSR2.
- chr2:95,274,449–95,291,308, 1 gene: PROM2.
- chr2:127,625,997–127,626,848, 1 gene (within-gene range 0–1): AC010976.2.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr2:232,442,034–232,548,115, 6 genes (within-gene range 0–2): DIS3L2P1, ALPI, ECEL1, PRSS56, CHRND, CHRNG.
- chr2:241,188,509–241,225,377, 1 gene: ANO7.
- chr3:49,640,483–49,723,973, 7 genes (within-gene range 0–2): BSN-AS1, APEH, MST1, AC099668.1, RNF123, AMIGO3, GMPPB.
- chr3:53,224,712–53,256,052, 1 gene: TKT.
- chr5:1,855,970–1,887,236, 4 genes: LINC02116, AC025183.2, IRX4, IRX4-AS1.
- chr5:139,647,299–139,683,882, 2 genes: CXXC5, CXXC5-AS1.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–2): POM121L6P.
- chr6:33,162,681–33,192,499, 1 gene: COL11A2.
- chr7:56,064,002–56,092,996, 2 genes: SUMF2, PHKG1.
- chr7:149,764,182–149,833,979, 2 genes: ZNF467, SSPOP.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr9:95,085,208–95,086,094, 4 genes (within-gene range 0–2): MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:124,257,606–124,353,307, 3 genes: NEK6, AL162724.2, AL162724.1.
- chr9:124,451,425–124,507,420, 2 genes: ADGRD2, NR5A1.
- chr9:126,589,594–126,613,700, 1 gene: AL161908.1.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr11:2,376,177–2,423,045, 4 genes (within-gene range 0–1): CD81, TSSC4, AC124057.1, TRPM5.
- chr14:103,525,010–103,537,073, 2 genes: AL133367.1, TRMT61A.
- chr15:25,232,387–25,250,940, 11 genes (within-gene range 0–2): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:89,873,570–89,938,761, 6 genes: TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:9,021,510–9,244,897, 3 genes: NTN1, AC005695.1, AC005695.3.
- chr17:42,025,576–42,098,479, 2 genes (within-gene range 0–2): ZNF385C, C17orf113.
- chr17:47,980,398–47,996,196, 1 gene (within-gene range 0–1): AC018521.4.
- chr17:63,928,740–63,972,918, 2 genes: CD79B, SCN4A.
- chr20:3,162,617–3,245,382, 5 genes: LZTS3, DDRGK1, ITPA, SLC4A11, AL109976.1.
- chr20:3,686,970–3,753,111, 2 genes: SIGLEC1, HSPA12B.
- chr20:64,102,394–64,242,253, 1 gene (within-gene range 0–2): MYT1.
- chr21:43,322,417–43,366,566, 3 genes: LINC00322, LINC01679, AP001046.1.
- chr21:45,405,165–45,513,720, 4 genes (within-gene range 0–1): COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815.
- chr22:18,906,028–19,034,564, 13 genes: DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1.
- chr22:19,045,256–19,061,843, 4 genes (within-gene range 0–2): Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:19,124,309–19,144,684, 4 genes (within-gene range 0–2): AC004471.2, TSSK1A, ESS2, TSSK2.
- chr22:23,059,415–23,145,021, 4 genes: RSPH14, GNAZ, Metazoa_SRP, U7.
- chr22:29,705,256–29,770,413, 7 genes: AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10.
- chr22:38,424,288–38,455,199, 3 genes: Z97056.1, KCNJ4, Z97056.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:63,121,833–63,158,021, 2 genes, copy number 5: LACTB, RPS27L.
- chr21:13,038,160–13,067,033, 2 genes, copy number 6: ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 2,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
